Somatic mutation profile of tumor specimen MMRF_1965_1_PB_CD138pos (aliquot MMRF_1965_1_PB_CD138pos_T3_KBS5U_L07258) from MMRF case MMRF_1965, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.4 years (22,053 days).
Specimen MMRF_1965_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64f940d1-e48e-4833-9cf3-c39fc69d0291.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1965_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1965_1_PB_CD3pos_C5_KBS5U_L07259; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b6f175c-cfcb-4632-8c02-25760fb384e2

The open-access MAF lists 898 somatic variants for this specimen: 283 protein-altering or splice-affecting, 124 silent, 491 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 258, Missense Mutation 244, Silent 124, Intron 113, 5'UTR 60, Nonsense Mutation 31, 5'Flank 25, 3'Flank 21, RNA 14, Splice Region 4, Frame Shift Del 1, Splice Site 1.

Variants (750 of 898; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.6115G>A p.E2039K | Missense Mutation (SNP) | VAF 208/347 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs864622251, CM094668, COSV53740536, COSV53772321; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 98/286 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 34/285 reads (12%) | catalogued as rs63750832, CM990715, COSV52279974, COSV99316104; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC131160.1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV100226150, COSV57701900; called by muse, mutect2, varscan2
- ADAM17 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV60397370; called by mutect2, varscan2
- ADGRB3 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 167/429 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as rs776701796; called by muse, mutect2, varscan2
- AGGF1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1238912433; called by muse, mutect2, varscan2
- ANO9 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); catalogued as rs777434943; called by muse, mutect2, varscan2
- ARFGEF3 | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as rs952834056, COSV52457413; called by muse, mutect2, varscan2
- ARHGAP21 | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11014178; called by muse, mutect2, varscan2
- ARSI | c.119C>G p.S40W | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs373063727; called by muse, mutect2, varscan2
- ATM | c.8683G>A p.E2895K | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53734559, COSV99069695; called by muse, mutect2, varscan2
- BAIAP2L1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.038); catalogued as COSV99134117; called by muse, mutect2, varscan2
- BAIAP3 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs371035129; called by muse, mutect2, varscan2
- BAZ2A | c.4310C>T p.S1437L | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs996772120; called by muse, mutect2, varscan2
- BCLAF1 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as rs754139777, COSV100786791; called by muse, mutect2, varscan2
- BCLAF1 | c.1605C>G p.I535M | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.973); catalogued as rs748242109; called by muse, mutect2, varscan2
- BTBD9 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV100023012; called by muse, mutect2, varscan2
- C1orf112 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 106/109 reads (97%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as COSV53683440; called by muse, mutect2, varscan2
- C6orf141 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV64586169; called by muse, mutect2, varscan2
- CASP14 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs140739098; called by muse, mutect2, varscan2
- CCDC136 | c.2448G>C p.K816N | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV99922874; called by muse, mutect2, varscan2
- CDK12 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 135/243 reads (56%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.833); catalogued as COSV71000091; called by muse, mutect2, varscan2
- CHL1 | c.2228C>G p.P743R (on ENST00000397491 / NM_001253387.1; = p.P759R on NM_006614.4) | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754312023; called by mutect2, varscan2
- COL14A1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1381094258; called by muse, mutect2, varscan2
- COPB1 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 42/108 reads (39%) | catalogued as rs1053617255; called by muse, mutect2, varscan2
- CORO1A | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs1483959987; called by muse, mutect2, varscan2
- DDX39B | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100385435, COSV58214075; called by muse, mutect2, varscan2
- DGUOK | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV51205286; called by muse, mutect2, varscan2
- DNAH6 | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1304818688; called by muse, mutect2, varscan2
- DNM2 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs778020908, COSV58968501; called by muse, mutect2
- DQX1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1384481063; called by muse, mutect2
- DSC3 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 126/307 reads (41%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV64574528; called by muse, mutect2, varscan2
- DYSF | c.5773del p.L1925Cfs*41 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | catalogued as COSV99248253; called by mutect2, pindel, varscan2
- ENG | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs1452543778; called by muse, mutect2
- EP300 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 68/138 reads (49%) | catalogued as COSV54326876; called by muse, mutect2, varscan2
- EXOC3 | c.2017C>G p.L673V | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as COSV59265894; called by muse, mutect2, varscan2
- FAM120A | c.1798C>G p.L600V | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as rs758792503; called by muse, mutect2, varscan2
- FANCC | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 112/229 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100002868, COSV56658258; called by muse, mutect2, varscan2
- FCHO1 | c.1688G>A p.R563K | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.262); catalogued as rs769532665; called by muse, mutect2, varscan2
- FCMR | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 178/391 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373086444; called by muse, mutect2, varscan2
- FYB1 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV60946000; called by muse, mutect2, varscan2
- FYB2 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV58586023; called by muse, mutect2, varscan2
- GALR1 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.421); catalogued as COSV100231846; called by muse, mutect2, varscan2
- GALR2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs766251513; called by muse, mutect2, varscan2
- GCOM1 | c.817A>G p.S273G | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as rs1374418659; called by muse, mutect2, varscan2
- GLA | c.708G>C p.W236C | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869312386, CM960769, COSV54509978; called by muse, mutect2, varscan2
- GMDS | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66413778; called by muse, mutect2, varscan2
- GRIPAP1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 75/92 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1569520273; called by muse, mutect2, varscan2
- GTF3C6 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 21/225 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as rs1448585962; called by muse, mutect2
- HMGB2 | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.378); catalogued as COSV99632579; called by muse, mutect2, varscan2
- IL27RA | c.340C>T p.L114F | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV99652342; called by muse, mutect2
- KATNIP | c.3236A>G p.N1079S | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560393620, COSV55193461; called by muse, mutect2, varscan2
- KCNIP4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV62853124; called by muse, mutect2
- KRT23 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as rs758409000, COSV52929270; called by muse, mutect2, varscan2
- KRTAP12-4 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs781859959, COSV59973816; called by muse, mutect2, varscan2
- LAMA2 | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.084); catalogued as COSV70343705; called by muse, varscan2
- LAMA2 | c.7508G>A p.R2503K | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70345964; called by muse, mutect2
- LPL | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV60932515; called by muse, mutect2, varscan2
- MARCHF9 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV56984654; called by muse, mutect2, varscan2
- MCTP2 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59150487; called by muse, mutect2, varscan2
- MRPL28 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.156); catalogued as rs1567320172; called by muse, mutect2, varscan2
- MUC17 | c.9077C>T p.S3026F | Missense Mutation (SNP) | VAF 69/451 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.831); catalogued as rs1220192316, COSV60305379; called by muse, mutect2, varscan2
- MXRA8 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as rs373508903; called by muse, mutect2, varscan2
- MYH14 | c.4174G>C p.E1392Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV99222634; called by muse, mutect2, varscan2
- MYH2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs767416022, COSV55445528; called by muse, mutect2, varscan2
- MYH3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs1396728749, COSV56870002; called by muse, mutect2, varscan2
- NAV1 | c.5590G>A p.D1864N | Missense Mutation (SNP) | VAF 137/912 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV55222246; called by muse, mutect2, varscan2
- NCKAP5L | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1565588122, COSV60134941; called by muse, mutect2, varscan2
- NPTX1 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 94/109 reads (86%) | catalogued as COSV60775721; called by muse, mutect2, varscan2
- OR4S2 | c.237G>A p.M79I | Missense Mutation (SNP) | VAF 77/126 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as rs764592618, COSV100412864, COSV56748527; called by muse, mutect2, varscan2
- OR8G1 | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.12); catalogued as COSV58379975; called by muse, mutect2, varscan2
- PCDHA7 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 86/120 reads (72%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.846); catalogued as COSV65342015; called by mutect2, varscan2
- PCDHGA10 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); catalogued as COSV53968380; called by muse, mutect2, varscan2
- PCDHGA5 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.006); catalogued as COSV99537264; called by muse, mutect2, varscan2
- PCDHGA7 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.029); catalogued as rs755956919, COSV54039160; called by muse, mutect2
- PHACTR2 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 83/174 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV59854458, COSV59859974, COSV99992009; called by muse, mutect2, varscan2
- PLCB1 | c.2753C>T p.S918L | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs759604666, COSV62060310; called by muse, mutect2, varscan2
- PLEKHG6 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs1413704967, COSV99164972; called by muse, mutect2, varscan2
- PNMA8B | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 148/305 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.827); catalogued as COSV66537275; called by muse, mutect2, varscan2
- POLR2E | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53125521; called by muse, mutect2, varscan2
- PPP1R12A | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 121/266 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs1189002862, COSV54106711; called by muse, mutect2, varscan2
- PRDM1 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 45/155 reads (29%) | catalogued as COSV64846690, COSV64847475; called by muse, mutect2, varscan2
- PRDM6 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as rs910507076; called by muse, mutect2, varscan2
- RASA4B | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1293574147; called by muse, mutect2, varscan2
- RNLS | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.079); catalogued as COSV59291566; called by muse, mutect2
- ROBO2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV59940690; called by muse, mutect2, varscan2
- RPL7 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs773722193; called by muse, mutect2, varscan2
- RPS19 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as CM167143; called by muse, mutect2
- RPTOR | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs372641715, COSV60809086; called by muse, varscan2
- RYR2 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63675798; called by muse, mutect2
- SAMD4A | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); catalogued as rs1227045080, COSV51876396; called by muse, mutect2, varscan2
- SCYL1 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as rs762912713; called by muse, mutect2, varscan2
- SDK1 | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV67387536; called by muse, mutect2, varscan2
- SIPA1 | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs945236130, COSV63139591; called by muse, mutect2, varscan2
- SLC25A22 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as rs1332876414; called by muse, mutect2, varscan2
- SLC26A4 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767477168; called by muse, mutect2, varscan2
- SLC2A10 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 105/197 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148324236; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A10 | c.1505G>C p.R502T (on ENST00000446997 / NM_001354461.2; = p.R472T on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV55797795; called by muse, mutect2, varscan2
- SMC4 | c.3658G>T p.E1220* | Nonsense Mutation (SNP) | VAF 86/182 reads (47%) | catalogued as COSV59088199; called by muse, varscan2
- SP140 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 28/48 reads (58%) | catalogued as rs1460200631; called by muse, mutect2, varscan2
- STAG1 | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99366368; called by muse, mutect2, varscan2
- STK36 | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs200344143; called by muse, mutect2, varscan2
- STRBP | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 60/136 reads (44%) | catalogued as COSV62118189; called by muse, mutect2, varscan2
- STXBP3 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as rs1394646096; called by muse, mutect2
- SYBU | c.224G>A p.C75Y (on ENST00000276646 / NM_001099754.2; = p.C74Y on NM_017786.6) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs368359388; called by muse, mutect2, varscan2
- TAF7 | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs367564007; called by muse, mutect2, varscan2
- TBL1XR1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV101467814; called by muse, mutect2, varscan2
- TCF20 | c.2046G>C p.Q682H | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs1258925350; called by muse, mutect2, varscan2
- TENM2 | c.3034G>A p.E1012K (on ENST00000518659 / NM_001122679.2; = p.E780K on NM_001080428.3) | Missense Mutation (SNP) | VAF 110/215 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1368396537; called by muse, mutect2, varscan2
- TLE3 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58166389; called by muse, mutect2, varscan2
- TLN1 | c.5308G>T p.E1770* | Nonsense Mutation (SNP) | VAF 61/114 reads (54%) | catalogued as COSV59210721; called by muse, mutect2, varscan2
- TOR2A | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV59122946; called by muse, mutect2, varscan2
- TRIML1 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60194308; called by muse, mutect2, varscan2
- TSC1 | c.2686C>T p.L896F | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs377132822, COSV53768413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.1954G>A p.E652K (on ENST00000591111; = p.E606K on NM_003319.4) | Missense Mutation (SNP) | VAF 75/159 reads (47%) | PolyPhen benign (0.003); catalogued as rs756924799, COSV60261974; called by muse, mutect2, varscan2
- UNC80 | c.5098C>A p.P1700T | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM160412; called by muse, mutect2, varscan2
- VSX2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56217473; called by muse, mutect2, varscan2
- ZBTB11 | c.1618C>G p.Q540E | Missense Mutation (SNP) | VAF 84/285 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); catalogued as COSV57244720; called by muse, mutect2, varscan2
- ZFPM1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100128299; called by muse, mutect2, varscan2
- ZNF366 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs762722295, COSV100574170; called by muse, mutect2, varscan2
- ZNF395 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765714526, COSV60429682; called by mutect2, varscan2
- ZNF420 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV58494123, COSV99077443; called by muse, mutect2, varscan2
- ZNF462 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 106/250 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV52948128; called by muse, mutect2, varscan2
- ZNF488 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 154/356 reads (43%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.087); catalogued as rs782380361; called by muse, mutect2, varscan2
- ZNF750 | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 57/71 reads (80%) | catalogued as rs377565207, COSV53961393, COSV53961753; called by muse, mutect2, varscan2
- ZSCAN1 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.301); catalogued as rs762191438; called by muse, mutect2, varscan2
- AASDHPPT | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 152/305 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAM19 | c.2428C>T p.H810Y | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.10933C>G p.L3645V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADNP | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ADRB3 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- AL645922.1 | c.3484G>A p.A1162T | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKIB1 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.806); called by muse, mutect2
- C11orf54 | c.658C>A p.P220T (on ENST00000331239; = p.P170T on NM_014039.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C20orf202 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- CACNG1 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 162/387 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CADPS | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- CBLC | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 71/120 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC77 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- CCDC88C | c.5426C>T p.S1809L | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDAN1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 116/233 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CEP162 | c.3766C>T p.Q1256* | Nonsense Mutation (SNP) | VAF 48/97 reads (49%) | called by muse, mutect2, varscan2
- CHCHD7 | c.113C>T p.S38F (on ENST00000355315 / NM_001011671.3; = p.S50F on NM_024300.4) | Missense Mutation (SNP) | VAF 167/332 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- CLN6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- CLVS2 | c.207C>G p.F69L | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- CMAS | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CNTRL | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- COA1 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- COL22A1 | c.3740G>A p.R1247K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CPEB3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRLF1 | c.438G>C p.K146N | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CS | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- DCHS1 | c.9772C>G p.L3258V | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DDX19B | c.1305G>T p.K435N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- DENND1B | c.771C>T p.C257= | Splice Region (SNP) | VAF 46/285 reads (16%) | called by muse, mutect2, varscan2
- DENND5B | c.2940G>C p.M980I | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DMBT1 | c.7147G>A p.D2383N (on ENST00000338354 / NM_001377530.1; = p.D1626N on NM_004406.3) | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNM3 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK11 | c.424C>G p.H142D | Missense Mutation (SNP) | VAF 82/92 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DYNC2H1 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- EDNRA | c.1241A>G p.N414S | Missense Mutation (SNP) | VAF 152/461 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EXTL3 | c.1381C>A p.P461T | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM83H | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT2 | c.10222G>C p.E3408Q | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAXDC2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- FNDC1 | c.1856C>G p.S619C | Missense Mutation (SNP) | VAF 98/175 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- FUBP3 | c.459_461del p.F154del | In Frame Del (DEL) | VAF 38/89 reads (43%) | called by mutect2, pindel, varscan2
- FXR2 | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- GALNT3 | c.1418G>C p.R473T | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GIMAP5 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 120/260 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GLI3 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- GOLGA4 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- GSPT1 | c.1495G>C p.D499H (on ENST00000420576 / NM_001130007.2; = p.D637H on NM_002094.4) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by mutect2, varscan2
- HELZ2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- HERPUD1 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 104/224 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- HMCN1 | c.4792G>C p.D1598H | Missense Mutation (SNP) | VAF 58/382 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- IDE | c.1668G>C p.M556I | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- IGHV3-53 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 118/332 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- INO80B | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- KAT6B | c.5398C>T p.Q1800* | Nonsense Mutation (SNP) | VAF 114/251 reads (45%) | called by muse, mutect2, varscan2
- KCNK17 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- KDM3B | c.5206-1G>C p.X1736_splice | Splice Site (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- KLHL3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- KRT75 | c.711C>T p.V237= | Splice Region (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- LAMA5 | c.10793C>T p.S3598L | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRFN1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRRK1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDGA2 | c.2917G>C p.E973Q (on ENST00000399232 / NM_001113498.2; = p.E675Q on NM_182830.4) | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); called by muse, varscan2
- MOGAT3 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MTMR6 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 74/123 reads (60%) | SIFT tolerated (0.38); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MUC17 | c.2834C>T p.S945L | Missense Mutation (SNP) | VAF 45/754 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2
- MUC20 | c.1931C>G p.T644R | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- MUSK | c.2557C>T p.H853Y | Missense Mutation (SNP) | VAF 126/281 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MYG1 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- MYO10 | c.4363G>A p.E1455K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- NAV3 | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKAPL | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- NLRP4 | c.2008C>G p.Q670E | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NR4A2 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRG2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- NRXN2 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- NUP210 | c.4903G>A p.D1635N | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.155); called by muse, mutect2
- PAN2 | c.8T>G p.F3C | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PARP8 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PCDHGB6 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- PELI1 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 37/231 reads (16%) | called by muse, mutect2, varscan2
- PHAX | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 49/92 reads (53%) | called by muse, mutect2, varscan2
- PHPT1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PLEC | c.2589G>A p.Q863= (on ENST00000322810 / NM_201380.4; = p.Q753= on NM_000445.5) | Splice Region (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- PNLIPRP2 | c.47G>C p.R16T | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PROS1 | c.829C>T p.Q277* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- PSMC1 | c.69G>C p.K23N | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PWWP2A | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.012); called by muse, varscan2
- PXDC1 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 60/151 reads (40%) | called by muse, mutect2, varscan2
- RANBP10 | c.1832C>G p.S611C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RASA4 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RASAL1 | c.1194C>G p.F398L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- RBM4 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 114/254 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- RHOG | c.-66C>A | Splice Region (SNP) | VAF 67/130 reads (52%) | called by muse, mutect2, varscan2
- RHOV | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- RICTOR | c.4646T>C p.I1549T | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.116); called by muse, mutect2
- RNF180 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ROCK1 | c.1566G>T p.Q522H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ROPN1 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RP2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 56/65 reads (86%) | SIFT tolerated (0.35); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RYR2 | c.11371C>T p.Q3791* | Nonsense Mutation (SNP) | VAF 13/428 reads (3%) | called by muse, mutect2
- SALL4 | c.2080G>C p.E694Q | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SAP30 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SARAF | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 76/82 reads (93%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- SBK2 | c.1015G>C p.V339L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- SDK2 | c.5906G>T p.S1969I | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINH1 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- SHBG | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- SLC12A8 | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 187/375 reads (50%) | called by muse, varscan2
- SLC25A16 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SLC25A3 | c.323C>A p.S108* (on ENST00000228318 / NM_005888.3; = p.S107* on NM_002635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 66/123 reads (54%) | called by muse, mutect2, varscan2
- SLC25A38 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC7A5 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC8B1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- SMARCD3 | c.559G>A p.E187K (on ENST00000262188 / NM_001003801.2; = p.E174K on NM_003078.4) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SNRPF | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SOGA3 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SP140L | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SP2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 144/288 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2
- SRP72 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SRRM4 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRSF4 | c.1005G>T p.R335S | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SSR3 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- STX19 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 118/234 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STXBP5 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TCP1 | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TESK2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2
- TGS1 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 153/290 reads (53%) | called by muse, mutect2, varscan2
- TMCC2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- TNFRSF11A | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- TRAF2 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- TRIM47 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TSHZ1 | c.1103C>T p.A368V (on ENST00000580243 / NM_001308210.2; = p.A323V on NM_005786.6) | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBB4B | c.362G>A p.R121K | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- TUT1 | c.1549G>T p.G517C | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TUT7 | c.2935C>G p.P979A | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBAP2L | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- UEVLD | c.1415G>C p.*472Sext*6 | Nonstop Mutation (SNP) | VAF 147/297 reads (49%) | called by muse, mutect2, varscan2
- UPP2 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- VANGL1 | c.23C>G p.S8C | Missense Mutation (SNP) | VAF 169/191 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VLDLR | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDFY3 | c.5752G>C p.D1918H | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- XIRP2 | c.2296G>C p.D766H (on ENST00000628543; = p.D941H on NM_152381.6) | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ZC3H7B | c.2683C>T p.L895F | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZMYM4 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF14 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.896); called by muse, mutect2
- ZNF160 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 100/300 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZNF18 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF195 | c.1751G>T p.G584V (on ENST00000399602 / NM_001130520.3; = p.G512V on NM_007152.5) | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF214 | c.1808G>A p.R603K | Missense Mutation (SNP) | VAF 71/148 reads (48%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF366 | c.223G>C p.G75R | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZNF415 | c.1375C>T p.Q459* | Nonsense Mutation (SNP) | VAF 76/242 reads (31%) | called by muse, mutect2, varscan2
- ZNF570 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ZNF622 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF780B | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- ZNF827 | c.1300C>T p.Q434* | Nonsense Mutation (SNP) | VAF 84/160 reads (53%) | called by muse, mutect2, varscan2
- ZWILCH | c.1623G>T p.K541N | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- ABCA2 | c.5859C>T p.T1953= (on ENST00000614293; = p.T1923= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/130 reads (51%) | called by muse, varscan2
- AC004593.2 | c.951G>A p.G317= | Silent (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- ACO1 | c.1713G>A p.E571= | Silent (SNP) | VAF 73/169 reads (43%) | called by muse, mutect2, varscan2
- ACOT4 | c.282G>A p.L94= | Silent (SNP) | VAF 60/149 reads (40%) | catalogued as rs1261487386; called by muse, mutect2, varscan2
- ADAMTS12 | c.2190A>G p.R730= | Silent (SNP) | VAF 21/317 reads (7%) | called by muse, mutect2
- AHNAK | c.7845C>T p.I2615= | Silent (SNP) | VAF 142/289 reads (49%) | catalogued as rs1399153372, COSV57210697; called by muse, mutect2, varscan2
- AK2 | c.9C>T p.P3= | Silent (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- AKAP13 | c.6333C>T p.F2111= (on ENST00000394518 / NM_007200.5; = p.F2115= on NM_006738.6) | Silent (SNP) | VAF 100/230 reads (43%) | called by muse, mutect2, varscan2
- ANO3 | c.1668C>T p.F556= | Silent (SNP) | VAF 31/228 reads (14%) | catalogued as COSV56803440; called by muse, mutect2, varscan2
- AP1B1 | c.612C>A p.I204= | Silent (SNP) | VAF 46/51 reads (90%) | called by muse, mutect2, varscan2
- BTNL2 | c.54C>T p.F18= | Silent (SNP) | VAF 136/336 reads (40%) | catalogued as COSV66630357; called by muse, mutect2, varscan2
- C19orf84 | c.84G>A p.A28= | Silent (SNP) | VAF 26/43 reads (60%) | catalogued as rs1047683939; called by muse, mutect2, varscan2
- C1orf131 | c.102G>A p.Q34= | Silent (SNP) | VAF 253/265 reads (95%) | called by muse, mutect2, varscan2
- C22orf39 | c.159C>T p.R53= | Silent (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2
- CAND2 | c.516C>T p.F172= (on ENST00000456430 / NM_001162499.2; = p.F79= on NM_012298.3) | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- CDH1 | c.2607C>T p.F869= | Silent (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- CDRT1 | c.1135C>T p.L379= | Silent (SNP) | VAF 66/159 reads (42%) | called by muse, mutect2, varscan2
- CEP135 | c.2238G>A p.K746= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- CFAP92 | c.3030C>G p.L1010= | Silent (SNP) | VAF 141/324 reads (44%) | called by muse, mutect2, varscan2
- CNOT1 | c.5550G>A p.E1850= | Silent (SNP) | VAF 57/104 reads (55%) | called by muse, mutect2, varscan2
- CRAMP1 | c.285G>A p.R95= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs763376463; called by muse, mutect2, varscan2
- CRAMP1 | c.1167G>A p.P389= | Silent (SNP) | VAF 62/148 reads (42%) | catalogued as rs777275882, COSV51961913; called by muse, mutect2, varscan2
- CRYBG2 | c.522G>A p.V174= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- CSMD3 | c.2523C>T p.I841= (on ENST00000297405 / NM_001363185.1; = p.I737= on NM_052900.3) | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV52112456; called by muse, mutect2, varscan2
- CXCL3 | c.114C>T p.V38= | Silent (SNP) | VAF 48/91 reads (53%) | called by muse, mutect2, varscan2
- DAPK1 | c.388C>T p.L130= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV63791995; called by muse, mutect2
- DNAH7 | c.9738G>A p.E3246= | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as COSV56771100; called by muse, mutect2, varscan2
- DNAH7 | c.6690C>T p.I2230= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as COSV56759913, COSV56760511; called by mutect2, varscan2
- DNAJC13 | c.6387G>A p.L2129= | Silent (SNP) | VAF 55/130 reads (42%) | called by muse, mutect2, varscan2
- DOCK5 | c.4254C>T p.I1418= | Silent (SNP) | VAF 21/35 reads (60%) | called by muse, mutect2, varscan2
- EMD | c.108G>A p.K36= | Silent (SNP) | VAF 55/60 reads (92%) | catalogued as rs1057521050; ClinVar: likely benign; called by muse, mutect2, varscan2
- EXOC5 | c.24C>T p.F8= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs1455512459; called by muse, mutect2, varscan2
- FAM166A | c.222G>A p.P74= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs761312533; called by muse, mutect2, varscan2
- FAM71E2 | c.1113C>T p.L371= | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as rs1304490796; called by muse, mutect2
- FAM83H | c.1236C>T p.F412= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1554623221; called by muse, mutect2, varscan2
- FCRLA | c.72C>T p.L24= (on ENST00000367959; = p.L7= on NM_032738.4) | Silent (SNP) | VAF 14/318 reads (4%) | catalogued as COSV52687599; called by muse, mutect2
- FERMT1 | c.444G>A p.K148= | Silent (SNP) | VAF 96/191 reads (50%) | catalogued as COSV99451408; called by muse, mutect2, varscan2
- FOXH1 | c.342G>C p.L114= | Silent (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- FOXO6 | c.9G>A p.A3= | Silent (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- FOXP2 | c.795G>A p.E265= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100647426, COSV63481875; called by muse, mutect2, varscan2
- GAMT | c.30C>T p.F10= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- GCC1 | c.138G>A p.L46= | Silent (SNP) | VAF 27/128 reads (21%) | called by muse, mutect2, varscan2
- GNL3L | c.1225C>T p.L409= | Silent (SNP) | VAF 65/71 reads (92%) | catalogued as rs1295483867; called by muse, mutect2, varscan2
- GPR139 | c.474G>A p.L158= | Silent (SNP) | VAF 53/104 reads (51%) | called by muse, mutect2, varscan2
- GSTZ1 | c.300T>C p.R100= | Silent (SNP) | VAF 62/129 reads (48%) | called by muse, mutect2, varscan2
- HAGH | c.684C>G p.L228= | Silent (SNP) | VAF 18/183 reads (10%) | called by muse, mutect2
- HIPK2 | c.1464C>T p.S488= | Silent (SNP) | VAF 75/172 reads (44%) | catalogued as rs144061745; called by muse, mutect2, varscan2
- HR | c.2871G>T p.L957= | Silent (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- HRC | c.210G>A p.E70= | Silent (SNP) | VAF 108/229 reads (47%) | called by muse, mutect2, varscan2
- HSF2 | c.9G>A p.Q3= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs770227286; called by muse, mutect2, varscan2
- IGSF23 | c.578G>A p.*193= | Silent (SNP) | VAF 104/216 reads (48%) | catalogued as COSV68806833; called by muse, varscan2
- ITIH1 | c.2688A>G p.G896= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- JCAD | c.1221C>T p.L407= | Silent (SNP) | VAF 27/186 reads (15%) | catalogued as rs768376016; called by muse, mutect2
- KIF5A | c.1083G>A p.A361= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as rs528282741, COSV99673453; called by muse, mutect2, varscan2
- KRT6B | c.894G>A p.L298= | Silent (SNP) | VAF 113/225 reads (50%) | catalogued as COSV52883421; called by muse, mutect2, varscan2
- LEPR | c.2151C>T p.I717= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2, varscan2
- LONP1 | c.729G>A p.K243= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- LTB4R2 | c.456C>T p.L152= (on ENST00000528054; = p.L121= on NM_019839.5) | Silent (SNP) | VAF 49/95 reads (52%) | called by muse, mutect2, varscan2
- MAIP1 | c.672G>A p.L224= | Silent (SNP) | VAF 27/145 reads (19%) | called by muse, mutect2, varscan2
- MFHAS1 | c.36G>A p.A12= | Silent (SNP) | VAF 15/16 reads (94%) | called by muse, mutect2, varscan2
- MPP4 | c.96G>A p.L32= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV59633929; called by muse, mutect2, varscan2
- MRPL32 | c.411C>T p.I137= | Silent (SNP) | VAF 110/236 reads (47%) | catalogued as COSV56239124; called by muse, mutect2, varscan2
- MRPL34 | c.243C>T p.R81= | Silent (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- MTHFSD | c.726C>T p.L242= (on ENST00000360900 / NM_001159377.2; = p.L241= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- MUL1 | c.1038G>A p.V346= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as COSV51642566; called by muse, mutect2, varscan2
- MYH14 | c.1800G>A p.A600= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV99223062, COSV99224573; called by muse, mutect2, varscan2
- MYRF | c.2064G>A p.L688= (on ENST00000278836 / NM_001127392.3; = p.L679= on NM_013279.4) | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as rs1369751470; called by muse, varscan2
- NHEJ1 | c.891C>A p.L297= | Silent (SNP) | VAF 93/232 reads (40%) | called by muse, mutect2, varscan2
- NHSL1 | c.4362G>A p.Q1454= | Silent (SNP) | VAF 55/125 reads (44%) | called by muse, mutect2, varscan2
- NUMBL | c.1650G>A p.G550= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs1255932673; called by muse, mutect2, varscan2
- OCA2 | c.1779C>T p.F593= | Silent (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- OR9A2 | c.297C>T p.L99= | Silent (SNP) | VAF 17/335 reads (5%) | called by muse, mutect2
- PAPPA | c.324C>T p.L108= | Silent (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- PDE3B | c.759G>A p.G253= | Silent (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- PHC1 | c.1215G>A p.Q405= | Silent (SNP) | VAF 46/351 reads (13%) | called by muse, mutect2, varscan2
- PID1 | c.198C>T p.V66= (on ENST00000354069 / NM_001330156.1; = p.V64= on NM_017933.5) | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1182386672, COSV62483465; called by muse, mutect2, varscan2
- PIGB | c.1008G>A p.K336= | Silent (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- PIM1 | c.288G>A p.V96= | Silent (SNP) | VAF 93/190 reads (49%) | called by muse, mutect2, varscan2
- PRDM8 | c.2025C>T p.F675= | Silent (SNP) | VAF 174/329 reads (53%) | called by muse, mutect2, varscan2
- PROSER2 | c.1056G>A p.L352= | Silent (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- PRPH | c.336C>T p.I112= | Silent (SNP) | VAF 43/86 reads (50%) | catalogued as rs754630788; called by muse, mutect2, varscan2
- PWWP2A | c.393G>A p.E131= | Silent (SNP) | VAF 54/132 reads (41%) | called by muse, varscan2
- RANBP3L | c.63G>A p.L21= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as rs1424938044; called by muse, mutect2
- RELB | c.840G>A p.Q280= | Silent (SNP) | VAF 81/186 reads (44%) | called by muse, mutect2, varscan2
- RIBC1 | c.459G>A p.L153= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- RNF19B | c.303C>T p.F101= | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2
- SFRP4 | c.687C>T p.P229= | Silent (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- SKAP2 | c.132G>A p.K44= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- SLC33A1 | c.291C>T p.L97= | Silent (SNP) | VAF 43/122 reads (35%) | called by muse, mutect2, varscan2
- SLC43A3 | c.1170C>T p.L390= | Silent (SNP) | VAF 27/50 reads (54%) | called by muse, mutect2, varscan2
- SLC5A6 | c.1707C>T p.L569= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as COSV100143211; called by muse, mutect2, varscan2
- SLC7A7 | c.1290C>T p.F430= | Silent (SNP) | VAF 50/108 reads (46%) | catalogued as rs368164901; called by muse, mutect2, varscan2
- SLC9A5 | c.1441C>T p.L481= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV100236960, COSV55360075; called by muse, mutect2
- SLCO1C1 | c.51G>A p.V17= | Silent (SNP) | VAF 128/338 reads (38%) | catalogued as rs377286815, COSV56879743; called by muse, mutect2, varscan2
- SNX25 | c.1659C>T p.L553= | Silent (SNP) | VAF 53/112 reads (47%) | called by muse, mutect2, varscan2
- SPARCL1 | c.1233G>A p.E411= | Silent (SNP) | VAF 106/239 reads (44%) | catalogued as COSV56802730; called by muse, mutect2, varscan2
- SPAST | c.183C>T p.F61= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV100188460, COSV59515052; called by muse, mutect2, varscan2
- SPATA48 | c.1266G>C p.V422= | Silent (SNP) | VAF 124/259 reads (48%) | called by muse, mutect2, varscan2
- SRMS | c.1455A>G p.R485= | Silent (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- SRPK2 | c.66G>A p.P22= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs1270208415; called by muse, mutect2, varscan2
- STARD9 | c.3360G>C p.L1120= | Silent (SNP) | VAF 135/306 reads (44%) | called by muse, mutect2, varscan2
- SYT4 | c.516C>T p.V172= | Silent (SNP) | VAF 73/184 reads (40%) | called by muse, mutect2, varscan2
- TGIF1 | c.579C>T p.L193= (on ENST00000330513 / NM_001374396.1; = p.L213= on NM_003244.4) | Silent (SNP) | VAF 159/355 reads (45%) | catalogued as rs1256384293; called by muse, mutect2, varscan2
- TLK1 | c.1725C>T p.L575= | Silent (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- TMEM200C | c.516C>T p.I172= | Silent (SNP) | VAF 48/317 reads (15%) | catalogued as COSV67309285; called by muse, mutect2, varscan2
- TOMM34 | c.762C>G p.L254= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- TRIO | c.3819G>A p.V1273= | Silent (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- TSPYL5 | c.132C>T p.L44= | Silent (SNP) | VAF 36/59 reads (61%) | called by muse, mutect2, varscan2
- TTC28 | c.5704C>T p.L1902= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as rs181049098; called by muse, mutect2, varscan2
- TUBA4A | c.276C>G p.L92= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV99944676, COSV99944715; called by muse, mutect2, varscan2
- TUBA4B | c.162C>A p.I54= | Silent (SNP) | VAF 102/211 reads (48%) | called by muse, mutect2, varscan2
- TXLNA | c.213C>T p.V71= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as rs769339074; called by muse, mutect2, varscan2
- TXNRD1 | c.358C>T p.L120= (on ENST00000525566 / NM_001093771.3; = p.L22= on NM_003330.4) | Silent (SNP) | VAF 60/140 reads (43%) | called by muse, varscan2
- USP19 | c.1210C>T p.L404= | Silent (SNP) | VAF 88/226 reads (39%) | catalogued as rs775020572; called by muse, mutect2, varscan2
- USP20 | c.1872C>T p.I624= | Silent (SNP) | VAF 228/494 reads (46%) | called by muse, varscan2
- VAX2 | c.387C>T p.G129= | Silent (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- VWA5B2 | c.1068C>G p.L356= | Silent (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- WDR36 | c.105G>A p.L35= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV72411354; called by muse, mutect2, varscan2
- WNK4 | c.1182G>A p.P394= | Silent (SNP) | VAF 75/156 reads (48%) | catalogued as rs777411138, COSV55906084; called by muse, mutect2, varscan2
- WWTR1 | c.723G>A p.Q241= | Silent (SNP) | VAF 17/42 reads (40%) | called by muse, varscan2
- ZFP64 | c.900G>A p.G300= | Silent (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- ZNF18 | c.1503C>T p.F501= | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as COSV59552863; called by muse, mutect2
- ZNF397 | c.159C>T p.F53= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- ZNF827 | c.2979G>T p.G993= | Silent (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- ABCC8 | c.1817+54C>A | Intron (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- AC004951.3 | n.694G>A | RNA (SNP) | VAF 34/58 reads (59%) | called by muse, mutect2, varscan2
- AC007064.4 | n.185A>G | RNA (SNP) | VAF 18/22 reads (82%) | called by muse, mutect2, varscan2
- AC009093.9 | n.61C>T | RNA (SNP) | VAF 39/58 reads (67%) | catalogued as rs1488453932; called by muse, mutect2, varscan2
- AC022415.2 | c.*1348G>A | 3'UTR (SNP) | VAF 48/364 reads (13%) | called by muse, mutect2, varscan2
- AC024651.2 | chr15:97874427 G>A | 5'Flank (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- AC099548.2 | chr7:143836712 G>A | 5'Flank (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*5743G>A | 3'UTR (SNP) | VAF 41/113 reads (36%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.-228G>A | 5'UTR (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- ADCY1 | c.*8814G>C | 3'UTR (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- ADGRB3 | c.*82G>A | 3'UTR (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- ADGRL3 | chr4:62071998 A>T | 3'Flank (SNP) | VAF 91/207 reads (44%) | catalogued as rs1359063028; called by muse, mutect2, varscan2
- AGO1 | c.*4422C>G | 3'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- AHI1 | chr6:135497928 G>A | 5'Flank (SNP) | VAF 24/46 reads (52%) | catalogued as rs984661576; called by muse, mutect2, varscan2
- AIFM1 | c.968-63C>G | Intron (SNP) | VAF 16/149 reads (11%) | called by muse, mutect2, varscan2
- AKAP9 | chr7:91940922 T>C | 5'Flank (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2, varscan2
- ALDH18A1 | c.*798G>A | 3'UTR (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- ALDH1L2 | c.*3893T>G | 3'UTR (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- ALKBH5 | c.-10C>T | 5'UTR (SNP) | VAF 17/47 reads (36%) | catalogued as rs751172747; called by muse, mutect2, varscan2
- ANAPC15 | chr11:72106699 G>C | 3'Flank (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- ANK3 | c.2615-1716C>G | Intron (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- ANKFY1 | c.-27G>A | 5'UTR (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2, varscan2
- ANKRD13B | c.250+50C>T | Intron (SNP) | VAF 37/57 reads (65%) | called by muse, mutect2, varscan2
- ANKRD31 | c.-171C>T | 5'UTR (SNP) | VAF 22/54 reads (41%) | catalogued as COSV57164547; called by muse, mutect2, varscan2
- ANP32E | c.*2190C>T | 3'UTR (SNP) | VAF 48/216 reads (22%) | called by muse, mutect2, varscan2
- ANTXR2 | c.*5524C>T | 3'UTR (SNP) | VAF 41/68 reads (60%) | catalogued as rs927201999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP1B1 | c.*206C>G | 3'UTR (SNP) | VAF 71/79 reads (90%) | called by muse, mutect2, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 29/48 reads (60%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- APBB2 | c.*3358G>A | 3'UTR (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- APPL1 | c.*782C>T | 3'UTR (SNP) | VAF 66/134 reads (49%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.*2396G>A | 3'UTR (SNP) | VAF 8/68 reads (12%) | catalogued as rs1241228341; called by muse, mutect2, varscan2
- ARHGAP6 | c.589-11175C>T | Intron (SNP) | VAF 113/124 reads (91%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.97-1335G>A | Intron (SNP) | VAF 20/281 reads (7%) | called by muse, mutect2
- ARID1B | c.2841-176G>C | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- ARL17B | c.*242C>T | 3'UTR (SNP) | VAF 46/309 reads (15%) | called by muse, varscan2
- ASB2 | c.-92G>A | 5'UTR (SNP) | VAF 70/146 reads (48%) | called by muse, mutect2, varscan2
- ASGR2 | c.-60C>T | 5'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- ASIC1 | c.559-199G>T | Intron (SNP) | VAF 44/161 reads (27%) | called by muse, varscan2
- ASPH | c.-107G>A | 5'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- ATAD1 | c.*2336C>G | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ATM | c.*2215C>T | 3'UTR (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- ATXN1 | c.*3998C>A | 3'UTR (SNP) | VAF 49/117 reads (42%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.1144-50C>T | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs939868384; called by muse, mutect2
- BACE1 | c.*2404G>C | 3'UTR (SNP) | VAF 4/93 reads (4%) | called by muse, mutect2
- BACH2 | c.*5288C>T | 3'UTR (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- BCL7A | c.*999G>A | 3'UTR (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
- BORCS7 | c.*996C>G | 3'UTR (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- BRSK2 | c.*938G>C | 3'UTR (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- BRSK2 | c.*1301G>A | 3'UTR (SNP) | VAF 56/126 reads (44%) | called by muse, mutect2
- BTBD19 | c.-29C>T | 5'UTR (SNP) | VAF 68/154 reads (44%) | called by muse, mutect2, varscan2
- BZW1 | c.-10-518G>C | Intron (SNP) | VAF 65/136 reads (48%) | called by muse, mutect2, varscan2
- CALM2 | c.3+11C>A | Intron (SNP) | VAF 72/147 reads (49%) | called by muse, varscan2
- CAMK1D | c.*2424G>A | 3'UTR (SNP) | VAF 47/102 reads (46%) | catalogued as rs545803666; called by muse, mutect2, varscan2
- CAMK2A | c.*1290G>T | 3'UTR (SNP) | VAF 59/136 reads (43%) | called by muse, mutect2, varscan2
- CAMK2A | c.*970G>C | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- CAMK4 | c.*7608G>C | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- CAPN7 | c.-177C>T | 5'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- CAST | chr5:96662273 del G | 5'Flank (DEL) | VAF 17/56 reads (30%) | called by mutect2, pindel, varscan2
- CBL | c.*3138C>G | 3'UTR (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- CCDC62 | c.*334G>C | 3'UTR (SNP) | VAF 69/146 reads (47%) | called by muse, mutect2, varscan2
- CCND2 | c.-250G>A | 5'UTR (SNP) | VAF 57/94 reads (61%) | catalogued as rs956074804; called by muse, mutect2, varscan2
- CCR7 | c.*723C>T | 3'UTR (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- CCSER2 | c.*3830G>A | 3'UTR (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- CDC42BPA | c.*338G>C | 3'UTR (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- CEACAM19 | c.*265G>A | 3'UTR (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- CENPL | c.*224C>G | 3'UTR (SNP) | VAF 112/687 reads (16%) | called by muse, mutect2, varscan2
- CENPP | c.*5566C>G | 3'UTR (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- CEP120 | c.-182G>A | 5'UTR (SNP) | VAF 42/81 reads (52%) | catalogued as rs1017488532; called by muse, mutect2, varscan2
- CEP128 | c.*402C>T | 3'UTR (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- CEP192 | c.4257+69C>G | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- CHD2 | c.62+125G>A | Intron (SNP) | VAF 57/105 reads (54%) | catalogued as rs531333338; called by muse, mutect2
- CHORDC1 | c.493-1536C>T | Intron (SNP) | VAF 32/49 reads (65%) | catalogued as rs1173022364; called by muse, mutect2, varscan2
- CHPF2 | c.-1091A>C | 5'UTR (SNP) | VAF 17/159 reads (11%) | called by muse, mutect2, varscan2
- CHRNA5 | c.-17C>T | 5'UTR (SNP) | VAF 23/52 reads (44%) | catalogued as COSV55138656; called by muse, mutect2, varscan2
- CIT | c.*975C>T | 3'UTR (SNP) | VAF 12/133 reads (9%) | catalogued as rs772668842; called by muse, mutect2
- CLDN2 | c.*15G>A | 3'UTR (SNP) | VAF 72/85 reads (85%) | called by muse, mutect2, varscan2
- CLEC12A | c.10+60G>A | Intron (SNP) | VAF 79/188 reads (42%) | called by muse, mutect2, varscan2
- CLINT1 | c.*1492G>C | 3'UTR (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2, varscan2
- CLK1 | c.-1+242C>G | Intron (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- CLN3 | c.389-11C>T | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- CNNM1 | c.*942C>T | 3'UTR (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- CNTLN | c.*31G>A | 3'UTR (SNP) | VAF 162/360 reads (45%) | called by muse, mutect2, varscan2
- COA1 | c.265-61C>G | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- COG2 | c.72+145G>A | Intron (SNP) | VAF 33/52 reads (63%) | called by muse, mutect2, varscan2
- COL4A3 | c.*11G>A | 3'UTR (SNP) | VAF 20/277 reads (7%) | called by muse, mutect2
- COPS3 | c.937-92G>A | Intron (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- CPNE4 | chr3:132037722 G>A | 5'Flank (SNP) | VAF 152/291 reads (52%) | called by muse, mutect2, varscan2
- CRACR2B | c.459-82C>T | Intron (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- CRCP | c.*1637G>A | 3'UTR (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2, varscan2
- CTDSP1 | c.657+128C>T | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as rs1010459594; called by muse, mutect2, varscan2
- CTSA | c.*70C>G | 3'UTR (SNP) | VAF 71/162 reads (44%) | called by muse, mutect2, varscan2
- CTSZ | c.*93G>A | 3'UTR (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- CYP11B1 | c.955-38C>T | Intron (SNP) | VAF 108/223 reads (48%) | called by muse, mutect2, varscan2
- DBH | c.*160C>T | 3'UTR (SNP) | VAF 111/256 reads (43%) | called by muse, varscan2
- DCHS1 | c.*422C>T | 3'UTR (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- DCP2 | c.*1594A>G | 3'UTR (SNP) | VAF 28/94 reads (30%) | called by muse, mutect2, varscan2
- DDX11 | c.2372+34G>C | Intron (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- DDX11 | c.2457+22G>C | Intron (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- DDX18 | c.1692+24G>A | Intron (SNP) | VAF 77/208 reads (37%) | catalogued as COSV54306076; called by muse, mutect2, varscan2
- DDX5 | chr17:64507270 C>T | 5'Flank (SNP) | VAF 7/17 reads (41%) | catalogued as COSV56748319; called by muse, mutect2
- DENND2B | c.-25-15934G>C | Intron (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- DFFA | c.*1826G>A | 3'UTR (SNP) | VAF 62/135 reads (46%) | catalogued as rs1173686337; called by muse, mutect2, varscan2
- DHRS4L2 | c.666-1528G>C | Intron (SNP) | VAF 118/422 reads (28%) | catalogued as COSV58729290; called by muse, mutect2, varscan2
- DHX37 | c.3389-53G>C | Intron (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- DLGAP1 | c.2724+135G>A | Intron (SNP) | VAF 31/68 reads (46%) | catalogued as COSV100228690; called by muse, mutect2, varscan2
- DLL4 | c.*111C>G | 3'UTR (SNP) | VAF 95/223 reads (43%) | called by muse, mutect2, varscan2
- DLX2 | c.*504C>T | 3'UTR (SNP) | VAF 14/27 reads (52%) | catalogued as rs1411155484; called by muse, mutect2, varscan2
- DMXL1 | c.*1421A>G | 3'UTR (SNP) | VAF 43/143 reads (30%) | called by muse, mutect2, varscan2
- DNAJA1 | c.*271G>A | 3'UTR (SNP) | VAF 152/340 reads (45%) | called by muse, mutect2, varscan2
- DNAJB5 | c.*995C>T | 3'UTR (SNP) | VAF 9/68 reads (13%) | catalogued as rs1352279025; called by muse, mutect2, varscan2
- DNAJC19 | c.*277C>T | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- DSEL | c.*3236G>A | 3'UTR (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- DUSP15 | c.12+321G>C | Intron (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- DVL3 | c.*2002A>G | 3'UTR (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.5978-111C>T | Intron (SNP) | VAF 6/17 reads (35%) | catalogued as rs1184345316; called by muse, mutect2, varscan2
- EHD1 | c.*385G>A | 3'UTR (SNP) | VAF 19/138 reads (14%) | called by muse, mutect2, varscan2
- EIF3B | c.-29G>A | 5'UTR (SNP) | VAF 8/21 reads (38%) | catalogued as rs953999980; called by muse, mutect2, varscan2
- EIF4A1 | c.*471G>A | 3'UTR (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- ELFN2 | c.*2414G>A | 3'UTR (SNP) | VAF 61/151 reads (40%) | called by muse, varscan2
- ELFN2 | c.*2332G>A | 3'UTR (SNP) | VAF 47/122 reads (39%) | called by muse, varscan2
- EMB | c.197-120C>G | Intron (SNP) | VAF 4/17 reads (24%) | catalogued as rs1357935053; called by mutect2, varscan2
- EML2 | chr19:45642158 G>A | 5'Flank (SNP) | VAF 68/111 reads (61%) | called by muse, mutect2, varscan2
- EPHA7 | c.*1920T>C | 3'UTR (SNP) | VAF 33/64 reads (52%) | called by muse, mutect2, varscan2
- EPS8 | c.736+10C>T | Intron (SNP) | VAF 43/114 reads (38%) | catalogued as rs778388265; called by muse, mutect2, varscan2
- ERGIC3 | c.160-18G>A | Intron (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- ERMN | c.*2090C>G | 3'UTR (SNP) | VAF 42/105 reads (40%) | called by muse, mutect2, varscan2
- EXOC6B | c.1980+2165G>C | Intron (SNP) | VAF 58/114 reads (51%) | called by muse, mutect2, varscan2
- EXT1 | c.-754C>T | 5'UTR (SNP) | VAF 62/143 reads (43%) | called by muse, mutect2, varscan2
- EYS | c.1766+23G>A | Intron (SNP) | VAF 98/193 reads (51%) | called by muse, mutect2, varscan2
- F13A1 | c.*1481T>G | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- FAM110D | c.*150G>A | 3'UTR (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- FAM160A2 | c.2215+91C>G | Intron (SNP) | VAF 54/160 reads (34%) | catalogued as rs1226626957; called by muse, mutect2, varscan2
- FAM189B | c.-37G>A | 5'UTR (SNP) | VAF 187/190 reads (98%) | called by muse, mutect2, varscan2
- FAM83A | c.*1536G>A | 3'UTR (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- FBXL7 | c.740-1219G>A | Intron (SNP) | VAF 49/105 reads (47%) | called by muse, mutect2, varscan2
- FEZ1 | c.498+124C>A | Intron (SNP) | VAF 24/43 reads (56%) | called by mutect2, varscan2
- FIBIN | c.-156G>A | 5'UTR (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- FLRT2 | c.*2994G>A | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- FLVCR1 | c.*1463C>T | 3'UTR (SNP) | VAF 5/22 reads (23%) | catalogued as rs1190289503; called by muse, mutect2
- FMR1 | c.-39C>T | 5'UTR (SNP) | VAF 8/9 reads (89%) | catalogued as COSV99503776; called by muse, mutect2, varscan2
- FN3K | c.591+151C>T | Intron (SNP) | VAF 23/30 reads (77%) | called by muse, mutect2, varscan2
- FOLH1B | n.1832C>T | RNA (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- FOXG1 | c.*55G>A | 3'UTR (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- FOXL1 | c.*713C>T | 3'UTR (SNP) | VAF 25/88 reads (28%) | catalogued as COSV100206397; called by muse, mutect2, varscan2
- FOXL1 | c.*1610G>C | 3'UTR (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- FOXN2 | c.*3814G>A | 3'UTR (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- FSIP1 | c.*2C>T | 3'UTR (SNP) | VAF 202/428 reads (47%) | catalogued as COSV52954005, COSV99527657; called by muse, mutect2, varscan2
- FUT4 | c.*2239G>A | 3'UTR (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034826 G>T | 5'Flank (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- FZD6 | c.177+7522C>G | Intron (SNP) | VAF 45/50 reads (90%) | called by muse, mutect2, varscan2
- GAB1 | chr4:143473646 C>T | 3'Flank (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- GABRB2 | c.*1240G>A | 3'UTR (SNP) | VAF 53/128 reads (41%) | called by mutect2, varscan2
- GALC | c.195+366C>T | Intron (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- GALNT13 | c.*1684C>T | 3'UTR (SNP) | VAF 35/80 reads (44%) | called by muse, varscan2
- GAMT | c.*34C>T | 3'UTR (SNP) | VAF 28/52 reads (54%) | called by muse, mutect2, varscan2
- GATB | c.*153C>G | 3'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2
- GBP1 | c.*995G>C | 3'UTR (SNP) | VAF 15/17 reads (88%) | called by muse, mutect2, varscan2
- GCLC | c.759+596G>A | Intron (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- GLB1L3 | c.1287+109C>T | Intron (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- GLIPR1L1 | c.*332G>T | 3'UTR (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- GNA12 | c.526-29390C>T | Intron (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- GOLM1 | c.*1526C>G | 3'UTR (SNP) | VAF 50/105 reads (48%) | called by muse, mutect2, varscan2
- GPAT4 | c.*1079C>T | 3'UTR (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- GPI | chr19:34365072 C>T | 5'Flank (SNP) | VAF 29/65 reads (45%) | catalogued as rs889711964; called by muse, mutect2, varscan2
- GPR146 | c.*523G>C | 3'UTR (SNP) | VAF 30/71 reads (42%) | called by muse, mutect2, varscan2
- GPR158 | c.-1G>A | 5'UTR (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- GPR162 | c.*120G>A | 3'UTR (SNP) | VAF 47/111 reads (42%) | called by muse, mutect2, varscan2
- GPR3 | c.*846C>G | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- GPRC5A | c.*4586C>T | 3'UTR (SNP) | VAF 47/90 reads (52%) | called by muse, mutect2, varscan2
- GRHL1 | c.1016-41G>C | Intron (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- GRIK3 | c.*313C>G | 3'UTR (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- H1-0 | c.-191G>A | 5'UTR (SNP) | VAF 21/29 reads (72%) | catalogued as rs999948546; called by muse, mutect2, varscan2
- HABP2 | c.*64G>T | 3'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- HACD3 | c.*17G>A | 3'UTR (SNP) | VAF 17/29 reads (59%) | catalogued as rs1422172122; called by muse, mutect2, varscan2
- HAPLN1 | c.*1363C>T | 3'UTR (SNP) | VAF 60/136 reads (44%) | called by muse, mutect2, varscan2
- HDAC2 | c.*3175G>C | 3'UTR (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- HDGFL1 | c.*9G>A | 3'UTR (SNP) | VAF 59/139 reads (42%) | catalogued as rs761228552, COSV100014533; called by muse, mutect2, varscan2
- HECTD1 | c.4982-421G>A | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2
- HERPUD1 | c.-46C>T | 5'UTR (SNP) | VAF 73/163 reads (45%) | called by muse, mutect2
- HERPUD1 | c.*691G>A | 3'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2
- HESX1 | c.*97T>G | 3'UTR (SNP) | VAF 30/64 reads (47%) | catalogued as rs1315253153; called by muse, mutect2, varscan2
- HLA-DOA | c.*753G>A | 3'UTR (SNP) | VAF 75/173 reads (43%) | called by muse, mutect2, varscan2
- HLA-DPA1 | c.-80C>T | 5'UTR (SNP) | VAF 133/281 reads (47%) | called by muse, mutect2, varscan2
- HLX | c.-189G>A | 5'UTR (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- HOXA2 | c.392-41C>G | Intron (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- HOXC11 | c.*506C>G | 3'UTR (SNP) | VAF 13/176 reads (7%) | catalogued as COSV99678440; called by muse, mutect2
- HSCB | c.236+18G>A | Intron (SNP) | VAF 34/38 reads (89%) | catalogued as rs781643400; called by muse, mutect2, varscan2
- HSPB7 | c.*624C>T | 3'UTR (SNP) | VAF 6/141 reads (4%) | called by muse, mutect2
- HTR4 | c.*83C>T | 3'UTR (SNP) | VAF 17/166 reads (10%) | catalogued as COSV58790026; called by muse, mutect2, varscan2
- HTR7 | c.*982G>C | 3'UTR (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- IDE | c.*1244G>A | 3'UTR (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- IER3 | c.*640G>C | 3'UTR (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- IGFN1 | c.1242-326C>T | Intron (SNP) | VAF 13/204 reads (6%) | catalogued as rs1185317638; called by muse, mutect2
- IL10RA | c.*774C>T | 3'UTR (SNP) | VAF 27/185 reads (15%) | called by muse, mutect2, varscan2
- IL22RA2 | c.*62C>T | 3'UTR (SNP) | VAF 7/63 reads (11%) | catalogued as rs770731699; called by muse, mutect2, varscan2
- IL5RA | c.*414C>T | 3'UTR (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2
- INF2 | c.701+562C>T | Intron (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- INO80D | c.*9648G>C | 3'UTR (SNP) | VAF 60/153 reads (39%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.*614G>A | 3'UTR (SNP) | VAF 18/308 reads (6%) | called by muse, mutect2
- IRF2BPL | c.-880G>A | 5'UTR (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- ISL1 | c.-155G>A | 5'UTR (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- ITGAV | c.*1927G>A | 3'UTR (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- JADE1 | c.1503+1953C>T | Intron (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2
- JPH1 | c.-101G>A | 5'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- JPH3 | c.-63C>T | 5'UTR (SNP) | VAF 105/193 reads (54%) | called by muse, mutect2, varscan2
- KAZN | c.-589G>A | 5'UTR (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- KCNJ5 | chr11:128917060 C>T | 3'Flank (SNP) | VAF 52/164 reads (32%) | called by muse, mutect2, varscan2
- KDM2B | c.*793C>G | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- KIAA0930 | c.*4746C>T | 3'UTR (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- KIF17 | c.*246C>A | 3'UTR (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- KIF1C | c.*1235C>G | 3'UTR (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- KIF6 | c.*5745G>A | 3'UTR (SNP) | VAF 10/196 reads (5%) | catalogued as rs1420417484; called by muse, mutect2
- KIRREL1 | c.*1171C>T | 3'UTR (SNP) | VAF 23/111 reads (21%) | called by mutect2, varscan2
- KLF5 | c.*1526T>C | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- KLHL14 | chr18:32773338 G>A | 5'Flank (SNP) | VAF 11/281 reads (4%) | called by muse, mutect2
- KLHL8 | c.*1387C>T | 3'UTR (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- KPNA6 | c.*1523C>T | 3'UTR (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- KRT6A | c.*278C>T | 3'UTR (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- LAMB1 | c.-42C>T | 5'UTR (SNP) | VAF 73/155 reads (47%) | catalogued as rs1206583645; called by muse, mutect2, varscan2
- LARP6 | c.*172G>C | 3'UTR (SNP) | VAF 48/118 reads (41%) | called by muse, mutect2, varscan2
- LCE5A | c.*83C>T | 3'UTR (SNP) | VAF 118/127 reads (93%) | catalogued as COSV100524283; called by muse, varscan2
- LDHC | chr11:18451607 C>G | 3'Flank (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- LDLRAD3 | c.*1896A>T | 3'UTR (SNP) | VAF 26/85 reads (31%) | called by mutect2, varscan2
- LEKR1 | c.*463A>G | 3'UTR (SNP) | VAF 103/221 reads (47%) | called by muse, mutect2, varscan2
- LEPR | c.*2144G>A | 3'UTR (SNP) | VAF 47/109 reads (43%) | called by muse, mutect2, varscan2
- LGALS17A | n.413G>C | RNA (SNP) | VAF 87/277 reads (31%) | called by muse, mutect2, varscan2
- LINC00518 | n.833C>G | RNA (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- LINC01551 | n.1255-5272C>T | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- LINC01556 | n.278C>T | RNA (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2
- LINC02118 | n.164C>T | RNA (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- LIX1 | c.483+2132G>A | Intron (SNP) | VAF 11/390 reads (3%) | called by muse, mutect2
- LRP1 | c.1227+33G>A | Intron (SNP) | VAF 26/240 reads (11%) | catalogued as rs1403408014; called by muse, mutect2, varscan2
- LRRC14 | c.*909C>T | 3'UTR (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- LRRC27 | chr10:132376019 G>A | 3'Flank (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- LZTS3 | c.*1533C>G | 3'UTR (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- MAB21L2 | c.*398G>A | 3'UTR (SNP) | VAF 7/39 reads (18%) | catalogued as rs760545420; called by muse, mutect2, varscan2
- MAGIX | chrX:49166712 G>A | 3'Flank (SNP) | VAF 38/70 reads (54%) | called by muse, mutect2, varscan2
- MAP2K6 | c.366+56C>T | Intron (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- MAP3K13 | c.*2273C>G | 3'UTR (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+5410G>C | Intron (SNP) | VAF 57/217 reads (26%) | called by muse, mutect2, varscan2
- MAPK8IP1P2 | n.492G>C | RNA (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- MAT1A | c.*701G>C | 3'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- MCUR1 | c.-126G>A | 5'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as rs1291985967; called by muse, mutect2, varscan2
- MDGA1 | c.*5188G>T | 3'UTR (SNP) | VAF 92/192 reads (48%) | called by muse, mutect2, varscan2
- MDS2 | n.322C>T | RNA (SNP) | VAF 75/155 reads (48%) | catalogued as rs1342466663; called by muse, mutect2, varscan2
- MED30 | c.336+19G>A | Intron (SNP) | VAF 60/100 reads (60%) | called by muse, mutect2, varscan2
- MESD | c.*1260C>G | 3'UTR (SNP) | VAF 47/90 reads (52%) | catalogued as rs541115159; called by muse, mutect2, varscan2
- MEX3B | c.*899C>G | 3'UTR (SNP) | VAF 28/86 reads (33%) | catalogued as rs923257895; called by muse, mutect2, varscan2
- MFSD14A | c.-91C>G | 5'UTR (SNP) | VAF 17/18 reads (94%) | catalogued as rs1440704214; called by muse, mutect2, varscan2
- MGAT3 | c.*2135C>T | 3'UTR (SNP) | VAF 5/105 reads (5%) | called by muse, mutect2
- MINDY4 | c.1678-15C>T | Intron (SNP) | VAF 46/105 reads (44%) | catalogued as rs1442661420; called by muse, mutect2, varscan2
- MIR29B2 | chr1:207802710 G>C | 5'Flank (SNP) | VAF 9/52 reads (17%) | catalogued as rs1054309479; called by muse, mutect2
- MIR520D | n.86G>A | RNA (SNP) | VAF 31/76 reads (41%) | catalogued as rs746447038; called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46112105 G>C | 5'Flank (SNP) | VAF 59/200 reads (30%) | called by muse, mutect2
- MITF | c.-36C>T | 5'UTR (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- MMACHC | c.*446C>T | 3'UTR (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- MME | c.*2382C>T | 3'UTR (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- MPPED2 | c.*1022G>A | 3'UTR (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- MTHFR | c.*4897C>T | 3'UTR (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- MTMR8 | c.*261G>C | 3'UTR (SNP) | VAF 47/55 reads (85%) | called by muse, mutect2, varscan2
- MUC20P1 | n.1034G>A | RNA (SNP) | VAF 15/293 reads (5%) | called by muse, mutect2
- MUTYH | c.36+279G>A | Intron (SNP) | VAF 34/206 reads (17%) | called by muse, varscan2
- MYO1C | c.*1049G>A | 3'UTR (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- NAPB | c.*1065G>T | 3'UTR (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- NARS1 | c.1384-38G>C | Intron (SNP) | VAF 96/214 reads (45%) | called by muse, mutect2
- NCAPD3 | c.2783-319C>T | Intron (SNP) | VAF 28/92 reads (30%) | catalogued as rs978115119; called by muse, mutect2
- NDUFA3 | c.*76+12G>A | Intron (SNP) | VAF 9/282 reads (3%) | catalogued as rs987559395; called by muse, mutect2
- NDUFA4 | c.-79C>T | 5'UTR (SNP) | VAF 58/146 reads (40%) | called by muse, mutect2, varscan2
- NDUFA5 | c.*1599G>C | 3'UTR (SNP) | VAF 60/105 reads (57%) | called by muse, mutect2, varscan2
- NDUFC1 | c.-222+931G>C | Intron (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- NEK4 | c.*245G>C | 3'UTR (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- NEUROG2 | c.*437G>A | 3'UTR (SNP) | VAF 48/126 reads (38%) | catalogued as rs990614236; called by muse, mutect2, varscan2
- NFKBIA | c.-10C>T | 5'UTR (SNP) | VAF 22/47 reads (47%) | catalogued as rs760886864; called by muse, mutect2, varscan2
- NKX2-1 | c.*797T>G | 3'UTR (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- NKX2-1 | c.*482G>A | 3'UTR (SNP) | VAF 27/62 reads (44%) | catalogued as rs918902794; called by muse, mutect2, varscan2
- NOP9 | c.*2887C>T | 3'UTR (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- NOS1AP | c.*447C>T | 3'UTR (SNP) | VAF 84/357 reads (24%) | called by muse, mutect2, varscan2
- NR1D1 | c.-420C>T | 5'UTR (SNP) | VAF 69/149 reads (46%) | called by muse, mutect2, varscan2
- NR2E1 | c.-257C>T | 5'UTR (SNP) | VAF 66/145 reads (46%) | called by muse, mutect2, varscan2
- NSD2 | c.1881+4136G>A | Intron (SNP) | VAF 46/95 reads (48%) | called by muse, mutect2, varscan2
- NTNG2 | c.1223-79G>T | Intron (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- NUBP2 | c.-53G>A | 5'UTR (SNP) | VAF 18/140 reads (13%) | catalogued as rs1266597715, COSV51907231; called by muse, mutect2, varscan2
- NUMB | chr14:73275203 C>T | 3'Flank (SNP) | VAF 49/93 reads (53%) | called by muse, mutect2, varscan2
- NUS1 | c.*1794C>G | 3'UTR (SNP) | VAF 70/146 reads (48%) | called by muse, mutect2, varscan2
- OLIG1 | c.*1006G>T | 3'UTR (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- OR2T33 | chr1:248272668 G>A | 3'Flank (SNP) | VAF 17/118 reads (14%) | called by mutect2, varscan2
- OR8H1 | c.-25C>T | 5'UTR (SNP) | VAF 165/377 reads (44%) | catalogued as rs779324381; called by muse, mutect2, varscan2
- OR9Q1 | c.*409T>G | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- OSBPL7 | c.-87-11C>G | Intron (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- OTULINL | c.*2044G>A | 3'UTR (SNP) | VAF 35/107 reads (33%) | catalogued as rs1441566312; called by muse, mutect2, varscan2
- P2RY13 | c.*157G>T | 3'UTR (SNP) | VAF 57/122 reads (47%) | catalogued as rs192372273; called by muse, mutect2, varscan2
- P4HB | c.*714G>C | 3'UTR (SNP) | VAF 33/44 reads (75%) | called by muse, mutect2, varscan2
- PACSIN1 | c.*1420G>A | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- PAICS | c.-51-29G>A | Intron (SNP) | VAF 41/67 reads (61%) | called by muse, mutect2, varscan2
- PAK6 | c.*549C>T | 3'UTR (SNP) | VAF 49/96 reads (51%) | catalogued as COSV53046761; called by muse, mutect2, varscan2
- PAPLN | c.171-45G>T | Intron (SNP) | VAF 68/147 reads (46%) | called by muse, mutect2, varscan2
- PARD3B | c.*3552G>A | 3'UTR (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- PARVA | c.798+38A>G | Intron (SNP) | VAF 108/235 reads (46%) | called by muse, mutect2, varscan2
- PAX2 | c.-167_-148del | 5'UTR (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- PAX9 | c.*201G>A | 3'UTR (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- PCDHB7 | c.*894G>A | 3'UTR (SNP) | VAF 42/97 reads (43%) | called by muse, mutect2, varscan2
- PDCD6IP | c.-20C>T | 5'UTR (SNP) | VAF 40/105 reads (38%) | called by muse, mutect2, varscan2
- PDIA3 | c.*1639G>T | 3'UTR (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- PEG10 | c.*2038G>C | 3'UTR (SNP) | VAF 35/64 reads (55%) | called by muse, mutect2, varscan2
- PENK | c.139-1831G>A | Intron (SNP) | VAF 53/105 reads (50%) | called by muse, mutect2, varscan2
- PEX26 | c.*1125C>G | 3'UTR (SNP) | VAF 63/67 reads (94%) | catalogued as rs1169221037; called by muse, mutect2, varscan2
- PFKFB2 | chr1:207079563 C>G | 3'Flank (SNP) | VAF 9/212 reads (4%) | called by muse, mutect2
- PGGHG | c.*1270C>T | 3'UTR (SNP) | VAF 36/77 reads (47%) | catalogued as rs1298758632; called by muse, mutect2, varscan2
- PGGT1B | c.*1538C>T | 3'UTR (SNP) | VAF 74/190 reads (39%) | catalogued as rs890352189; called by muse, mutect2, varscan2
- PHPT1 | chr9:136849257 G>A | 5'Flank (SNP) | VAF 48/135 reads (36%) | called by muse, varscan2
- PIK3C3 | c.*5910C>T | 3'UTR (SNP) | VAF 40/70 reads (57%) | called by muse, mutect2, varscan2
- PLA2G4E | c.*557C>T | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*6498G>A | 3'UTR (SNP) | VAF 35/59 reads (59%) | catalogued as rs1016556818; called by muse, mutect2, varscan2
- PLPP3 | c.-196G>C | 5'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- PLPP5 | c.635-221G>C | Intron (SNP) | VAF 106/244 reads (43%) | called by muse, varscan2
- POLE2 | c.*39C>T | 3'UTR (SNP) | VAF 47/201 reads (23%) | called by muse, mutect2, varscan2
- POLR3E | c.-38-17C>G | Intron (SNP) | VAF 88/192 reads (46%) | called by muse, mutect2, varscan2
- POU6F1 | chr12:51188347 G>C | 3'Flank (SNP) | VAF 48/112 reads (43%) | called by muse, mutect2, varscan2
- PPHLN1 | c.1024+379C>T | Intron (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- PPP1R12B | c.*6162G>A | 3'UTR (SNP) | VAF 31/141 reads (22%) | called by muse, mutect2, varscan2
- PPP1R9A | c.*3825G>A | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- PRADC1 | c.-56A>T | 5'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- PRR18 | c.*1070_*1071insTT | 3'UTR (INS) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- PRR23A | c.*958G>A | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- PRRC1 | c.1128+722C>T | Intron (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- PRRX1 | chr1:170663233 C>T | 5'Flank (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.839-105G>A | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- PTAR1 | c.*3683G>A | 3'UTR (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- PTPRD | c.*370G>A | 3'UTR (SNP) | VAF 43/79 reads (54%) | catalogued as rs990083213, COSV100645962; called by muse, mutect2, varscan2
- PTPRK | c.*51G>A | 3'UTR (SNP) | VAF 82/819 reads (10%) | called by muse, mutect2, varscan2
- PUM2 | c.*2693C>G | 3'UTR (SNP) | VAF 87/196 reads (44%) | called by muse, mutect2, varscan2
- PXN | c.*335C>A | 3'UTR (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- PYGO1 | c.*797G>A | 3'UTR (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- RAB30 | chr11:82978986 G>A | 3'Flank (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- RAB6B | c.*3688C>T | 3'UTR (SNP) | VAF 54/116 reads (47%) | called by muse, mutect2, varscan2
- RAD21 | c.1470+292C>T | Intron (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- RASGRP3 | c.*982G>C | 3'UTR (SNP) | VAF 118/259 reads (46%) | called by muse, mutect2, varscan2
- RBM28 | c.-80C>T | 5'UTR (SNP) | VAF 25/50 reads (50%) | catalogued as COSV99775440; called by muse, mutect2, varscan2
- RBM4B | c.-13+48C>T | Intron (SNP) | VAF 121/231 reads (52%) | called by muse, mutect2, varscan2
- RCC1 | c.-268C>G | 5'UTR (SNP) | VAF 58/118 reads (49%) | called by muse, mutect2, varscan2
- REPS1 | c.*292A>G | 3'UTR (SNP) | VAF 27/55 reads (49%) | catalogued as rs1465493081; called by muse, mutect2, varscan2
- RHOU | c.-9C>T | 5'UTR (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- RICTOR | c.4136+354C>T | Intron (SNP) | VAF 58/108 reads (54%) | called by muse, mutect2, varscan2
148 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 148 other) are not listed here.
